Gene-level copy-number profile of tumor specimen TCGA-ER-A19Q-06A from TCGA case TCGA-ER-A19Q, project TCGA-SKCM (Skin Cutaneous Melanoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Malignant melanoma, NOS; Tissue or organ of origin: Skin, NOS; Age at diagnosis: 40.8 years (14,905 days).
Specimen TCGA-ER-A19Q-06A: Sample type: Metastatic; Tissue type: Tumor; Tumor descriptor: Metastatic; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-SKCM.a2d796eb-0499-4e28-bd42-5d55fd8c21aa.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-ER-A19Q-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 805 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/324d71da-326c-42e9-9cef-3863e830cd29

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 68; copy number 1: 10,607; copy number 2: 40,066; copy number 3: 3,150; copy number 4: 5,046; copy number 5: 1; copy number 6: 880.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-ER-A19Q-06A-11D-A191-01): tumor purity 0.63, ploidy 2.13, whole-genome doublings 0.

Homozygous deletions (total copy number 0; autosomes only): 68 genes in 2 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr9:20,331,446–22,214,672, 65 genes (broad region; genes not listed).
- chr18:54,357,906–54,424,632, 3 genes (within-gene range 0–1): C18orf54, SNRPGP2, CUPIN1P.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 881 genes in 2 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr11:65,745,729–103,479,863, 880 genes, copy number 6 (within-gene range 1–6) (broad region; genes not listed).
- chr17:74,043,452–74,154,212, 1 gene, copy number 5: LINC02074.

Autosomal genes at a single copy (total copy number 1): 8,186. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
